Gene-level copy-number profile of tumor specimen TCGA-DD-AACZ-01A from TCGA case TCGA-DD-AACZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 63.6 years (23,230 days).
Specimen TCGA-DD-AACZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d27e7cd1-b7bb-4f77-8619-ca1f6f9618aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a621d2b-9f5d-45e6-889f-38e4394001a9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 968; copy number 2: 12,825; copy number 3: 22,152; copy number 4: 11,265; copy number 5: 8,686; copy number 6: 2,665; copy number 7: 8; copy number 8: 233; copy number 9: 331; copy number 10: 569; copy number 12: 112.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACZ-01A-11D-A40Q-01): tumor purity 0.47, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr20:14,884,250–15,280,873, 5 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,253 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:99,489,559–100,153,779, 21 genes, copy number 8: AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P.
- chr8:69,424,849–145,066,685, 1,190 genes, copy number 7–12 (broad region; genes not listed).
- chr10:44,899,614–45,727,231, 32 genes, copy number 9 (within-gene range 6–9): AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4, AGAP10P, FAM21FP, AL645998.1.
- chr10:57,513,157–58,267,894, 6 genes, copy number 12: AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10.
- chr10:60,778,331–61,026,420, 4 genes, copy number 8: CDK1, RHOBTB1, RNU2-72P, LINC00845.

Autosomal genes at a single copy (total copy number 1): 966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
